Somatic mutation profile of tumor specimen 0DIOKC from CCDI case PBBUCK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.6 years (4,979 days).
Specimen 0DIOKC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f357c69-26cb-47fa-ab8f-c5cb488c89b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIOJV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0df996d8-6511-42eb-8f0e-d259bb150e3f

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 143/956 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6AP1 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 224/708 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM51 | c.996G>T p.G332= | Silent (SNP) | VAF 192/933 reads (21%) | catalogued as rs753477967, COSV55264667; called by muse, mutect2, varscan2
- ABCG1 | c.1158+39G>A | Intron (SNP) | VAF 53/237 reads (22%) | catalogued as rs141186591; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1162-33del | Intron (DEL) | VAF 108/483 reads (22%) | called by mutect2, varscan2
- ATP6V1B2 | c.1162-34A>T | Intron (SNP) | VAF 110/490 reads (22%) | called by mutect2, varscan2
